Gene-level copy-number profile of tumor specimen ALCH-AE0R-TTP1-A from ALCHEMIST case ALCH-AE0R, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.1 years (27,431 days).
Specimen ALCH-AE0R-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8ad6e21f-b128-47c6-bbb9-13315f5b431a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE0R-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,246 have no estimate.
https://portal.gdc.cancer.gov/files/549e563a-91e5-4328-90a2-78ef81df964f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 59; copy number 1: 979; copy number 2: 56,701; copy number 3: 601; copy number 4: 24; copy number 5: 5; copy number 6: 4; copy number 8: 1; copy number 13: 1; copy number 45: 1; copy number 49: 1.

Homozygous deletions (total copy number 0; autosomes only): 57 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:16,974,502–17,011,928, 5 genes: MFAP2, AL049569.2, AL049569.1, ATP13A2, AL049569.3.
- chr1:42,153,410–42,164,745, 2 genes: GUCA2B, GUCA2A.
- chr1:222,477,252–222,504,622, 2 genes: AL513314.2, RNU6-791P.
- chr2:20,667,144–20,679,243, 2 genes (within-gene range 0–2): GDF7, AC012065.3.
- chr2:241,800,916–241,817,413, 3 genes (within-gene range 0–2): AC131097.1, AC131097.2, NEU4.
- chr4:2,059,327–2,069,089, 1 gene: NAT8L.
- chr4:8,846,076–8,871,839, 2 genes: HMX1, AC116612.1.
- chr6:168,053,166–168,101,511, 1 gene: FRMD1.
- chr7:56,805,336–56,808,148, 1 gene: CICP28.
- chr7:102,471,469–102,478,907, 2 genes: MIR4467, POLR2J.
- chr9:42,830,337–42,950,827, 2 genes (within-gene range 0–1): ANKRD20A7P, RNU6-599P.
- chr10:117,128,521–117,138,301, 1 gene: VAX1.
- chr10:118,643,760–118,644,198, 1 gene: TOMM22P5.
- chr11:298,200–299,526, 1 gene: IFITM5.
- chr13:113,667,219–113,737,736, 1 gene: GRK1.
- chr14:73,537,143–73,543,796, 2 genes (within-gene range 0–2): ACOT1, NT5CP2.
- chr14:105,150,778–105,150,864, 1 gene (within-gene range 0–2): MIR6765.
- chr15:67,819,704–67,834,582, 1 gene (within-gene range 0–2): SKOR1.
- chr15:67,834,310–67,840,045, 2 genes (within-gene range 0–2): AC009292.1, RNU6-1.
- chr15:74,311,516–74,319,688, 1 gene (within-gene range 0–2): AC023300.2.
- chr16:15,134,075–15,134,145, 1 gene (within-gene range 0–2): MIR6511B2.
- chr16:88,731,180–88,741,425, 1 gene (within-gene range 0–2): AC138028.2.
- chr17:21,376,357–21,419,870, 1 gene: KCNJ12.
- chr20:25,248,085–25,298,012, 3 genes (within-gene range 0–2): PYGB, AL121772.2, AL121772.3.
- chr22:18,524,620–18,530,573, 3 genes: Metazoa_SRP, AC023490.3, TMEM191B.
- chr22:18,615,581–18,615,900, 1 gene: Metazoa_SRP.
- chr22:18,833,694–18,834,438, 1 gene (within-gene range 0–1): E2F6P1.
- chr22:21,028,718–21,032,840, 1 gene (within-gene range 0–2): SLC7A4.
- chr22:38,056,311–38,110,684, 5 genes: PICK1, AL031587.2, SLC16A8, BAIAP2L2, AL022322.1.
- chr22:42,126,499–42,149,455, 5 genes (within-gene range 0–2): CYP2D6, AC254562.1, AC254562.2, AC254562.3, CYP2D7.
- chr22:47,115,838–47,117,217, 1 gene (within-gene range 0–2): FP325331.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 13 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:2,234,251–2,234,499, 1 gene, copy number 5 (within-gene range 3–5): COX6B1P5.
- chr11:1,947,278–1,989,920, 2 genes, copy number 8–49: MRPL23, MRPL23-AS1.
- chr21:43,092,956–43,107,570, 1 gene, copy number 6: U2AF1.
- chr22:18,361,820–18,512,187, 5 genes, copy number 5–6: FAM230J, AC011718.1, FAM230A, AC023490.2, FAM247B.
- chr22:18,623,339–18,625,289, 1 gene, copy number 45: SUSD2P2.
- chr22:18,873,543–18,894,407, 2 genes, copy number 5: FAM230F, AC008103.1.
- chr22:21,466,423–21,471,269, 1 gene, copy number 13: TMEM191C.

Autosomal genes at a single copy (total copy number 1): 969. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
